Somatic mutation profile of tumor specimen TCGA-RY-A840-01A (aliquot TCGA-RY-A840-01A-11D-A36O-08) from TCGA case TCGA-RY-A840, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 47.9 years (17,501 days).
Specimen TCGA-RY-A840-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 978827aa-0421-402b-859c-698f9a618731.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RY-A840-10A (Blood Derived Normal), aliquot TCGA-RY-A840-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd01736f-fefe-4d1a-af80-e3f6512f0b2d

The open-access MAF lists 20 somatic variants for this specimen: 11 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 6, Intron 2, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 29/97 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACSM2B | c.13C>T p.R5* | Nonsense Mutation (SNP) | VAF 34/65 reads (52%) | catalogued as rs745852481, COSV61657708; called by muse, mutect2, varscan2
- CCDC106 | c.281A>C p.D94A | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99553224; called by muse, mutect2, varscan2
- CLUH | c.3767T>A p.L1256Q (on ENST00000435359; = p.L1295Q on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); catalogued as COSV101425838; called by muse, mutect2
- COL13A1 | c.1606G>A p.G536R (on ENST00000398978 / NM_001130103.2; = p.G479R on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1359566606, COSV62572241; called by muse, mutect2, varscan2
- CPAMD8 | c.4220C>T p.T1407I (on ENST00000651564; = p.T1360I on NM_015692.5) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.06); catalogued as COSV101488552; called by muse, mutect2, varscan2
- FGD2 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.202); catalogued as COSV51463733, COSV99236468; called by muse, mutect2
- KRTAP10-8 | c.403G>C p.V135L | Missense Mutation (SNP) | VAF 80/186 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100554858; called by muse, mutect2, varscan2
- RIPOR3 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs148432777; called by muse, mutect2, varscan2
- SCAMP3 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs563500300, COSV100226857; called by muse, mutect2, varscan2
- SMARCA4 | c.2953G>A p.E985K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1415464964, COSV60787372; called by muse, mutect2, varscan2
- FAM3B | c.63C>G p.A21= | Silent (SNP) | VAF 38/77 reads (49%) | catalogued as COSV100783761; called by muse, mutect2, varscan2
- LRRK1 | c.492G>A p.G164= | Silent (SNP) | VAF 61/121 reads (50%) | catalogued as rs183858799, COSV99441991; called by muse, mutect2, varscan2
- NEDD8 | c.22C>T p.L8= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99164653; called by muse, mutect2
- STX3 | c.838T>C p.L280= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as rs1177827064, COSV100276163; called by muse, mutect2
- TNFAIP8 | c.438C>T p.H146= | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as COSV57228115; called by muse, mutect2, varscan2
- TRIM24 | c.2265T>C p.Y755= (on ENST00000343526 / NM_015905.3; = p.Y721= on NM_003852.4) | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as COSV100631126; called by muse, mutect2, varscan2
- CLCN5 | c.17-32525T>A | Intron (SNP) | VAF 10/45 reads (22%) | catalogued as COSV101067270; called by muse, mutect2, varscan2
- FCRL2 | c.884-86G>A | Intron (SNP) | VAF 50/95 reads (53%) | catalogued as rs1167628941, COSV100829971; called by muse, mutect2, varscan2
- GRIN1 | c.*251A>G | 3'UTR (SNP) | VAF 4/45 reads (9%) | catalogued as rs1325798112, COSV100160572; called by muse, mutect2
